Somatic mutation profile of tumor specimen C3L-00981-01 (aliquot CPT0122720009) from CPTAC case C3L-00981, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 54.5 years (19,908 days).
Specimen C3L-00981-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c029bbc3-9d54-4fc6-b929-c23313ed5033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00981-31 (Blood Derived Normal), aliquot CPT0124680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45a1102-c649-46d1-971c-1016a1150153

The open-access MAF lists 114 somatic variants for this specimen: 87 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 17, Intron 7, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 3, RNA 2, Translation Start Site 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>T p.X155_splice | Splice Site (SNP) | VAF 164/620 reads (26%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBX6 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 167/676 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1443110513; called by muse, mutect2, varscan2
- CFAP251 | c.2161A>G p.M721V | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1350578010; called by muse, mutect2, varscan2
- CILP2 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 239/695 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV52278532; called by muse, mutect2, varscan2
- COL6A6 | c.2905G>C p.V969L | Missense Mutation (SNP) | VAF 119/328 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs530717316, COSV62020583; called by muse, mutect2, varscan2
- DNAH9 | c.11765A>G p.Y3922C | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1166035607; called by muse, mutect2, varscan2
- EYS | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs530200433, COSV60978648; called by muse, mutect2, varscan2
- EYS | c.1612G>T p.G538* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | catalogued as rs780233995; called by muse, mutect2, varscan2
- FAT3 | c.4031G>A p.R1344H | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs374766216; called by muse, mutect2, varscan2
- FOLR3 | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 33/1089 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV61529954; called by muse, mutect2
- GSTO1 | c.47del p.P16Rfs*14 | Frame Shift Del (DEL) | VAF 87/422 reads (21%) | catalogued as rs1564835315, COSV63846548; called by mutect2, pindel, varscan2
- H1-5 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 41/1122 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771262830, COSV100137908; called by muse, mutect2
- HLA-DOA | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57713518, COSV57714983, COSV57715838; called by muse, mutect2, varscan2
- ITK | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 132/708 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.127); catalogued as COSV70064736; called by muse, mutect2, varscan2
- KIF1A | c.4444G>A p.V1482I (on ENST00000320389 / NM_001379639.1; = p.V1474I on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/635 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs779019920; called by muse, mutect2, varscan2
- MYO18B | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 95/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577621514, COSV59146387; called by muse, mutect2, varscan2
- MYPN | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 253/1354 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV62731914; called by muse, mutect2, varscan2
- NUTM2G | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 37/797 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100672976; called by muse, mutect2
- ODF3L2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 356/868 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774779124, COSV52746048; called by muse, mutect2, varscan2
- PSORS1C1 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 62/359 reads (17%) | catalogued as COSV52536607; called by muse, mutect2, varscan2
- RAB21 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163512248; called by muse, mutect2
- SECISBP2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1564341747; called by muse, mutect2, varscan2
- STRIP2 | c.1796A>G p.H599R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs147388296; called by muse, varscan2
- TTN | c.102591C>A p.S34197R (on ENST00000591111; = p.S26773R on NM_003319.4) | Missense Mutation (SNP) | VAF 64/264 reads (24%) | PolyPhen possibly damaging (0.474); catalogued as COSV100614322; called by muse, mutect2, varscan2
- USP17L7 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 236/1306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61556573; called by muse, mutect2, varscan2
- WDR11 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 63/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54789156; called by muse, mutect2, varscan2
- ZNF592 | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 91/430 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs751321230; called by muse, mutect2, varscan2
- AMPD2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 198/444 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMH1 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- C10orf71 | c.1921C>G p.P641A | Missense Mutation (SNP) | VAF 149/837 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C11orf54 | c.8G>C p.C3S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- C9orf131 | c.885C>G p.H295Q | Missense Mutation (SNP) | VAF 112/475 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- CAPRIN2 | c.3085G>T p.G1029C | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC85A | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CD79B | c.542T>A p.L181Q | Missense Mutation (SNP) | VAF 214/1067 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH2 | c.2038A>G p.I680V | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 274/1315 reads (21%) | called by pindel, varscan2
- CDON | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP70 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.623); called by muse, mutect2
- CFAP54 | c.6263T>G p.I2088R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, varscan2
- CILP2 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 234/685 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CKAP5 | c.1669_1680del p.K557_P560del | In Frame Del (DEL) | VAF 45/358 reads (13%) | called by mutect2, pindel
- CLN3 | c.1012G>A p.D338N (on ENST00000360019 / NM_001286104.2; = p.D362N on NM_000086.2) | Missense Mutation (SNP) | VAF 159/818 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CTAGE9 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 186/915 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CUL1 | c.2255G>T p.C752F | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYB5R3 | c.767A>T p.E256V | Missense Mutation (SNP) | VAF 200/1012 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DNAH5 | c.3653G>T p.G1218V | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- DNAH5 | c.3652G>T p.G1218* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- ENO4 | c.346G>T p.A116S (on ENST00000622726; = p.A115S on NM_001242699.2) | Missense Mutation (SNP) | VAF 129/805 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FNDC1 | c.4249C>G p.P1417A | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FRMPD1 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 144/681 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUS | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 149/738 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- GOLGA8M | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 80/932 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.076); called by muse, varscan2
- HIF1A | c.1898_1904del p.E633Vfs*4 | Frame Shift Del (DEL) | VAF 62/259 reads (24%) | called by mutect2, pindel, varscan2
- IGFALS | c.255C>G p.N85K | Missense Mutation (SNP) | VAF 129/673 reads (19%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL21R | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAZF1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- KAZN | c.2061C>G p.I687M | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.178); called by muse, mutect2
- LCMT2 | c.133_136del p.A45Rfs*18 | Frame Shift Del (DEL) | VAF 55/400 reads (14%) | called by mutect2, pindel, varscan2
- LIPK | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MAP9 | c.200A>T p.N67I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- OR4A47 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PCARE | c.3820G>T p.D1274Y | Missense Mutation (SNP) | VAF 187/1040 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCDHGA6 | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 108/490 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PLA2G12B | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- PLEKHH1 | c.407C>A p.T136K | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PPP2R3B | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 154/900 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR2 | c.9979A>G p.K3327E | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SALL4 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 188/1409 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SALL4 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 185/1401 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A9 | c.986C>A p.P329Q (on ENST00000507527 / NM_001258428.2; = p.P305Q on NM_031467.3) | Missense Mutation (SNP) | VAF 20/437 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- SLC9A5 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SP140L | c.860-1G>A p.X287_splice | Splice Site (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 134/594 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 401/994 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, varscan2
- SV2C | c.2130T>A p.C710* | Nonsense Mutation (SNP) | VAF 109/473 reads (23%) | called by muse, mutect2, varscan2
- TAF3 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2
- TFAP2E | c.200_208delinsA p.G67Dfs*58 | Frame Shift Del (DEL) | VAF 111/550 reads (20%) | called by pindel, varscan2*
- TRPV4 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 199/990 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TSBP1 | c.1106G>C p.G369A (on ENST00000617061; = p.G374A on NM_006781.5) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBALD1 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- UNC80 | c.2482del p.Q828Rfs*10 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- VPS13B | c.9690-12_9690del p.X3230_splice | Splice Site (DEL) | VAF 61/175 reads (35%) | called by mutect2, pindel, varscan2
- VPS33A | c.1113T>A p.F371L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR81 | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YARS2 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 125/805 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF730 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS7 | c.246C>T p.Y82= | Silent (SNP) | VAF 208/1010 reads (21%) | catalogued as rs1440763015, COSV66307913; called by muse, mutect2, varscan2
- ASPRV1 | c.819A>G p.L273= | Silent (SNP) | VAF 117/437 reads (27%) | called by muse, mutect2, varscan2
- CELF1 | c.633A>C p.A211= | Silent (SNP) | VAF 134/567 reads (24%) | called by muse, mutect2, varscan2
- CUL1 | c.2256C>T p.C752= | Silent (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- HNF1A | c.549A>T p.G183= | Silent (SNP) | VAF 218/1291 reads (17%) | catalogued as CD133604; called by muse, mutect2, varscan2
- KNTC1 | c.804T>G p.V268= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- MFAP5 | c.436C>T p.L146= | Silent (SNP) | VAF 90/322 reads (28%) | catalogued as rs1292754708; called by muse, varscan2
- NCBP3 | c.510A>T p.T170= | Silent (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- OR4A47 | c.366G>T p.V122= | Silent (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- PIGG | c.1470G>C p.V490= (on ENST00000453061 / NM_001127178.3; = p.V482= on NM_017733.4) | Silent (SNP) | VAF 216/879 reads (25%) | called by muse, mutect2, varscan2
- PROCR | c.198G>A p.T66= | Silent (SNP) | VAF 65/714 reads (9%) | catalogued as rs200946979; called by muse, mutect2
- PTPRCAP | c.408G>A p.E136= | Silent (SNP) | VAF 143/616 reads (23%) | called by muse, mutect2, varscan2
- SCART1 | c.624G>A p.L208= | Silent (SNP) | VAF 167/845 reads (20%) | called by muse, mutect2, varscan2
- SP9 | c.1377G>A p.A459= | Silent (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1584G>T p.V528= | Silent (SNP) | VAF 292/797 reads (37%) | called by muse, mutect2, varscan2
- TSEN54 | c.1104C>A p.A368= | Silent (SNP) | VAF 78/327 reads (24%) | catalogued as COSV51393344; called by muse, mutect2, varscan2
- WDR72 | c.13C>T p.L5= | Silent (SNP) | VAF 91/546 reads (17%) | called by muse, mutect2, varscan2
- AK7 | c.2134-297G>A | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- ARVCF | c.210+3466G>A | Intron (SNP) | VAF 17/75 reads (23%) | catalogued as rs751146263; called by muse, mutect2
- C7orf65 | n.85G>T | RNA (SNP) | VAF 32/179 reads (18%) | catalogued as rs748395724; called by muse, mutect2, varscan2
- KATNIP | c.540+5893T>C | Intron (SNP) | VAF 67/291 reads (23%) | called by muse, mutect2, varscan2
- LINC02313 | n.315G>A | RNA (SNP) | VAF 21/98 reads (21%) | catalogued as rs1220038359; called by muse, mutect2, varscan2
- NHSL1 | c.203-2896G>C | Intron (SNP) | VAF 15/114 reads (13%) | catalogued as COSV100606942; called by muse, mutect2, varscan2
- PTPA | c.999+830C>G | Intron (SNP) | VAF 64/386 reads (17%) | called by muse, mutect2, varscan2
- SRL | c.62-3310G>C | Intron (SNP) | VAF 142/672 reads (21%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5245C>G | Intron (SNP) | VAF 40/237 reads (17%) | catalogued as rs779371194; called by muse, mutect2, varscan2
- ZSWIM8 | c.-27G>T | 5'UTR (SNP) | VAF 42/174 reads (24%) | catalogued as COSV65708408; called by muse, mutect2, varscan2
